Somatic mutation profile of tumor specimen TCGA-MB-A5YA-01A (aliquot TCGA-MB-A5YA-01A-11D-A29N-09) from TCGA case TCGA-MB-A5YA, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 63.3 years (23,115 days).
Specimen TCGA-MB-A5YA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ccf8f66d-958b-4c7d-8ef3-bb9cae4abcdc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MB-A5YA-10A (Blood Derived Normal), aliquot TCGA-MB-A5YA-10A-01D-A29N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/60919da8-e477-49b9-8b6a-8ce670be72c5

The open-access MAF lists 29 somatic variants for this specimen: 19 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 8, RNA 1, Nonsense Mutation 1, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.626_627del p.R209Kfs*6 | Frame Shift Del (DEL) | VAF 21/35 reads (60%) | catalogued as rs1057517840; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ARHGAP33 | c.1549G>A p.A517T | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.592); catalogued as rs996870005, COSV50129775; called by muse, mutect2, varscan2
- CFI | c.1550C>G p.S517C | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV101144736; called by muse, mutect2
- DOCK10 | c.965C>T p.T322M | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.222); catalogued as rs147869852, COSV51347099; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2530C>T p.P844S | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.934); catalogued as COSV100668870; called by muse, mutect2, varscan2
- GRID2 | c.299C>T p.T100M | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs200490934, COSV56199169; called by muse, mutect2, varscan2
- HERPUD1 | c.838A>G p.I280V | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.119); catalogued as rs995123952, COSV100296083; called by muse, mutect2
- IL5RA | c.1258T>G p.F420V | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV99843336; called by muse, mutect2, varscan2
- KCNK17 | c.881C>G p.P294R | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV100950304; called by muse, mutect2, varscan2
- MX1 | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as rs1298857808, COSV99912853; called by muse, mutect2, varscan2
- PABPC1L | c.514C>T p.H172Y | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.329); catalogued as COSV99408198; called by muse, mutect2
- PKP4 | c.3374A>G p.N1125S | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.111); catalogued as COSV100734001; called by muse, mutect2
- PLOD2 | c.352T>C p.F118L | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as COSV99283336; called by muse, mutect2, varscan2
- RAD54L2 | c.2933C>T p.T978I | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV99621872; called by muse, mutect2, varscan2
- SHANK2 | c.3580G>A p.G1194S | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs782016327, COSV99576137; called by muse, mutect2, varscan2
- TBC1D9B | c.3334G>A p.G1112S (on ENST00000356834 / NM_198868.3; = p.G1095S on NM_015043.4) | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV99481778; called by muse, mutect2, varscan2
- TMEM132E | c.740A>G p.K247R (on ENST00000321639; = p.K337R on NM_001304438.2) | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100396814; called by muse, mutect2, varscan2
- TMX2 | c.420C>G p.Y140* | Nonsense Mutation (SNP) | VAF 31/78 reads (40%) | catalogued as COSV99560393; called by muse, mutect2, varscan2
- TSPEAR | c.1307A>T p.H436L | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.029); catalogued as COSV100555541; called by muse, mutect2, varscan2
- DMXL2 | c.2046G>A p.Q682= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs778627888, COSV99198620; called by muse, mutect2, varscan2
- FAT2 | c.4200C>A p.G1400= | Silent (SNP) | VAF 4/45 reads (9%) | called by muse, mutect2
- HK2 | c.1452G>T p.L484= | Silent (SNP) | VAF 39/98 reads (40%) | catalogued as COSV99309589; called by muse, mutect2, varscan2
- LMOD1 | c.867A>G p.K289= | Silent (SNP) | VAF 30/72 reads (42%) | catalogued as rs1195741879, COSV100939279; called by muse, mutect2, varscan2
- NCKAP5 | c.846T>C p.D282= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV100494466; called by muse, mutect2, varscan2
- OR10J5 | c.816T>A p.V272= | Silent (SNP) | VAF 26/73 reads (36%) | catalogued as COSV100604842; called by muse, mutect2, varscan2
- PCDHA3 | c.1683C>T p.N561= | Silent (SNP) | VAF 6/124 reads (5%) | catalogued as COSV63543435; called by muse, mutect2
- ZCWPW1 | c.414A>G p.V138= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV100228424; called by muse, mutect2, varscan2
- BRMS1 | c.*173C>G | 3'UTR (SNP) | VAF 28/75 reads (37%) | catalogued as rs760790404, COSV100254999; called by muse, mutect2, varscan2
- DCHS2 | n.8129G>A | RNA (SNP) | VAF 17/46 reads (37%) | catalogued as COSV61768704; called by muse, mutect2, varscan2
